National Lung Screening Trial (NLST) participant 105719 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 55 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 43): Negative screen, minor abnormalities not suspicious for lung cancer.
- T1 (day 397): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality).
- T2 (day 732): Negative screen, minor abnormalities not suspicious for lung cancer.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer occurred after the screening years; study year of the first confirmed lung cancer: T4; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 1,593, study year T4. Site: upper lobe of lung (ICD-O-3 C34.1), determined from histology. Primary tumour location: right upper lobe. Histology: non-small cell carcinoma (ICD-O-3 8046/3). Cancer type as recorded on the NLST diagnostic evaluation form (the trial's best information on type): adenocarcinoma, NOS (ICD-O-3 8140). Grade: poorly differentiated (G3). Tumour size on pathology: 115 mm. AJCC 6th edition staging: stage IIB (best stage, from pathologic TNM); clinical T2 N1 M0 (stage IIB); pathologic T3 N0 M0 (stage IIB). AJCC 7th edition staging: stage IIB; clinical T3 N1 M0; pathologic T3 N0 M0.

Follow-up
Last known free of lung cancer: day 1,434.
